Somatic mutation profile of tumor specimen TCGA-4A-A93X-01A (aliquot TCGA-4A-A93X-01A-11D-A36X-10) from TCGA case TCGA-4A-A93X, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 58.4 years (21,348 days).
Specimen TCGA-4A-A93X-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 35f46d8e-07d0-49da-8c2a-f5daa8d70eda.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-4A-A93X-10A (Blood Derived Normal), aliquot TCGA-4A-A93X-10A-01D-A370-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/93e3a342-091f-41fa-be5e-8d89017ebdcd

The open-access MAF lists 103 somatic variants for this specimen: 81 protein-altering or splice-affecting, 19 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 62, Silent 19, Nonsense Mutation 6, Frame Shift Ins 5, Frame Shift Del 3, Splice Site 3, Splice Region 1, In Frame Del 1, RNA 1, Intron 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFE2L2 | c.246A>C p.E82D | Missense Mutation (SNP) | VAF 20/54 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV67960116, COSV67960221; called by muse, mutect2, varscan2
- PBRM1 | c.2128C>T p.R710* | Nonsense Mutation (SNP) | VAF 118/194 reads (61%) | hotspot (GDC flag); catalogued as COSV56260264, COSV56262552; called by muse, mutect2, varscan2
- ABCA8 | c.1785A>C p.K595N | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV99286956; called by muse, mutect2, varscan2
- AC011462.1 | c.1061A>T p.E354V | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); catalogued as COSV99524774; called by muse, mutect2, varscan2
- AHNAK2 | c.15703T>A p.F5235I | Missense Mutation (SNP) | VAF 36/52 reads (69%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV100319004; called by muse, mutect2, varscan2
- AP3M2 | c.57T>G p.H19Q | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1353847259, COSV99441928; called by muse, mutect2, varscan2
- ARFGEF2 | c.5086T>C p.Y1696H | Missense Mutation (SNP) | VAF 46/101 reads (46%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV100904487; called by muse, mutect2, varscan2
- ARHGEF10 | c.697+2T>G p.X233_splice (on ENST00000398564; = p.X208_splice on NM_014629.4) | Splice Site (SNP) | VAF 13/18 reads (72%) | catalogued as COSV100035658; called by muse, mutect2, varscan2
- ATXN2 | c.3742C>A p.Q1248K (on ENST00000550104; = p.Q1088K on NM_002973.4) | Missense Mutation (SNP) | VAF 99/167 reads (59%) | SIFT deleterious (0); PolyPhen benign (0.115); catalogued as COSV100374539, COSV57985521; called by muse, mutect2, varscan2
- BAZ2B | c.1886A>T p.D629V | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.84); catalogued as COSV100601027; called by muse, mutect2, varscan2
- BAZ2B | c.1785T>A p.D595E | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.87); PolyPhen benign (0.069); catalogued as COSV100601030; called by muse, mutect2, varscan2
- BICRAL | c.47C>T p.P16L | Missense Mutation (SNP) | VAF 101/240 reads (42%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.736); catalogued as COSV100018501; called by muse, mutect2, varscan2
- CBY2 | c.1099C>T p.Q367* | Nonsense Mutation (SNP) | VAF 55/120 reads (46%) | catalogued as COSV100137850; called by muse, mutect2, varscan2
- CDH18 | c.2009C>T p.A670V | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV99938491; called by muse, mutect2, varscan2
- CHEK2 | c.556C>A p.H186N (on ENST00000382580 / NM_001005735.2; = p.H143N on NM_007194.4) | Missense Mutation (SNP) | VAF 74/85 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM077520, COSV100102533; called by muse, mutect2, varscan2
- CSF2RB | c.1393A>G p.I465V | Missense Mutation (SNP) | VAF 51/59 reads (86%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99454484; called by muse, mutect2, varscan2
- DLG5 | c.3451G>C p.E1151Q | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.094); catalogued as COSV100967897; called by muse, mutect2, varscan2
- DMTF1 | c.908G>A p.G303D | Missense Mutation (SNP) | VAF 66/145 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100487520; called by muse, mutect2, varscan2
- DMXL1 | c.8933A>C p.N2978T | Missense Mutation (SNP) | VAF 62/138 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.093); catalogued as COSV100225013; called by muse, mutect2, varscan2
- EDRF1 | c.335A>T p.D112V | Missense Mutation (SNP) | VAF 60/168 reads (36%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.542); catalogued as COSV100524034; called by muse, mutect2, varscan2
- EML5 | c.4560A>C p.E1520D (on ENST00000380664; = p.E1528D on NM_183387.3) | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.913); catalogued as COSV100716231; called by muse, mutect2, varscan2
- EPM2A | c.968A>G p.K323R | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV100837653; called by muse, mutect2, varscan2
- ERC1 | c.983A>C p.E328A | Missense Mutation (SNP) | VAF 43/120 reads (36%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.78); catalogued as COSV100706769; called by muse, mutect2, varscan2
- FAT1 | c.8658A>C p.K2886N | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT tolerated (0.46); PolyPhen benign (0.049); catalogued as COSV101499653; called by muse, mutect2, varscan2
- FCER1A | c.596G>A p.R199H | Missense Mutation (SNP) | VAF 5/95 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs1433078324, COSV100929236, COSV63668193; called by muse, mutect2
- FLOT1 | c.792G>C p.Q264H | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.841); catalogued as COSV100899814; called by muse, mutect2, varscan2
- FOXA2 | c.709C>T p.P237S (on ENST00000377115 / NM_153675.3; = p.P243S on NM_021784.5) | Missense Mutation (SNP) | VAF 59/124 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs760812511, COSV65797167; called by muse, mutect2, varscan2
- FRYL | c.4795G>A p.A1599T | Missense Mutation (SNP) | VAF 82/198 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99978236; called by muse, mutect2, varscan2
- GPC2 | c.1427C>A p.A476E | Missense Mutation (SNP) | VAF 39/159 reads (25%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.758); catalogued as rs766096655, COSV99445098, COSV99445233; called by muse, mutect2, varscan2
- GSTCD | c.1324G>T p.G442C (on ENST00000360505 / NM_001031720.3; = p.G355C on NM_024751.3) | Missense Mutation (SNP) | VAF 53/131 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100853881; called by muse, mutect2, varscan2
- HEPACAM2 | c.1316G>T p.G439V (on ENST00000394468 / NM_001039372.4; = p.G427V on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.481); catalogued as COSV100506803; called by muse, mutect2, varscan2
- IFNG | c.359A>C p.N120T | Missense Mutation (SNP) | VAF 42/71 reads (59%) | SIFT tolerated (0.11); PolyPhen benign (0.071); catalogued as COSV99971303; called by muse, mutect2, varscan2
- IL1RL2 | c.393G>C p.E131D | Missense Mutation (SNP) | VAF 140/303 reads (46%) | SIFT tolerated (0.32); PolyPhen benign (0.105); catalogued as COSV99961117; called by muse, mutect2, varscan2
- KMT2A | c.3750G>T p.E1250D | Missense Mutation (SNP) | VAF 75/155 reads (48%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.039); catalogued as COSV100629928; called by muse, mutect2, varscan2
- LRP6 | c.3194A>C p.N1065T | Missense Mutation (SNP) | VAF 55/81 reads (68%) | SIFT deleterious (0.02); PolyPhen benign (0.27); catalogued as COSV99744538; called by muse, mutect2, varscan2
- MEI1 | c.2569G>T p.D857Y | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV100300374; called by muse, mutect2
- MGAM | c.5378C>T p.P1793L | Missense Mutation (SNP) | VAF 74/154 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV72074126; called by muse, mutect2, varscan2
- MYO1D | c.2762C>T p.T921M | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.118); catalogued as rs776654965, COSV59019143; called by muse, mutect2
- MYOM2 | c.88G>A p.D30N | Missense Mutation (SNP) | VAF 49/71 reads (69%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV100038433; called by muse, mutect2, varscan2
- MYZAP | c.1271G>T p.R424I (on ENST00000267853 / NM_001018100.5; = p.R396I on NM_152451.7) | Missense Mutation (SNP) | VAF 46/113 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99984871, COSV99985339; called by muse, mutect2, varscan2
- NAPEPLD | c.530C>T p.P177L | Missense Mutation (SNP) | VAF 74/166 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.102); catalogued as rs779636606, COSV100440085; called by muse, mutect2, varscan2
- NNT | c.835A>C p.K279Q | Missense Mutation (SNP) | VAF 129/246 reads (52%) | SIFT tolerated (0.44); PolyPhen benign (0.044); catalogued as COSV99239614; called by muse, mutect2, varscan2
- OAS3 | c.2781C>G p.F927L | Missense Mutation (SNP) | VAF 42/130 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57445222, COSV99966574; called by muse, mutect2, varscan2
- OR4E2 | c.481T>C p.F161L | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV100330160; called by muse, mutect2, varscan2
- PAXIP1 | c.3108C>A p.C1036* | Nonsense Mutation (SNP) | VAF 101/245 reads (41%) | catalogued as COSV101250087; called by muse, mutect2, varscan2
- PBRM1 | c.3875+1G>A p.X1292_splice (on ENST00000296302 / NM_001366071.2; = p.X1267_splice on NM_018313.5) | Splice Site (SNP) | VAF 17/55 reads (31%) | catalogued as COSV56266529, COSV56285083; called by muse, mutect2, varscan2
- PELO | c.485A>G p.K162R | Missense Mutation (SNP) | VAF 82/187 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.101); catalogued as COSV99252195; called by muse, mutect2, varscan2
- PLEKHA8 | c.639G>A p.R213= | Splice Region (SNP) | VAF 220/457 reads (48%) | catalogued as rs1318378360, COSV99322258; called by muse, mutect2, varscan2
- PLOD3 | c.1213A>G p.I405V | Missense Mutation (SNP) | VAF 50/98 reads (51%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV99778304; called by muse, mutect2, varscan2
- PNPLA6 | c.3643G>T p.V1215F (on ENST00000414982 / NM_001166111.2; = p.V1167F on NM_006702.5) | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV99654540; called by muse, mutect2, varscan2
- R3HCC1L | c.206G>C p.R69P | Missense Mutation (SNP) | VAF 26/178 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as COSV100107573, COSV54403462; called by muse, mutect2, varscan2
- RAB26 | c.592del p.X198_splice | Splice Site (DEL) | VAF 28/115 reads (24%) | catalogued as rs1300433925; called by mutect2, pindel, varscan2
- RPS16 | c.393G>C p.K131N | Missense Mutation (SNP) | VAF 78/122 reads (64%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); catalogued as COSV99261910; called by muse, mutect2, varscan2
- SCARF1 | c.974A>G p.H325R | Missense Mutation (SNP) | VAF 41/145 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.139); catalogued as COSV99557260; called by muse, mutect2, varscan2
- SCRN2 | c.602T>G p.I201S | Missense Mutation (SNP) | VAF 31/52 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); catalogued as COSV99274341, COSV99274376; called by muse, mutect2, varscan2
- SETD2 | c.4883A>C p.N1628T | Missense Mutation (SNP) | VAF 70/121 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100340075, COSV57430011; called by muse, mutect2, varscan2
- SLC34A1 | c.91T>C p.Y31H | Missense Mutation (SNP) | VAF 40/88 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV100184124; called by muse, mutect2, varscan2
- SPTBN4 | c.6335C>T p.T2112M | Missense Mutation (SNP) | VAF 35/61 reads (57%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV100152163; called by muse, mutect2, varscan2
- SRRM2 | c.3670G>T p.E1224* | Nonsense Mutation (SNP) | VAF 64/106 reads (60%) | catalogued as COSV100071537, COSV57068863; called by muse, mutect2, varscan2
- STAG2 | c.2464C>T p.Q822* | Nonsense Mutation (SNP) | VAF 38/41 reads (93%) | catalogued as COSV54363822; called by muse, mutect2, varscan2
- THOC3 | c.454G>A p.D152N | Missense Mutation (SNP) | VAF 116/449 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.025); catalogued as COSV99442267; called by muse, mutect2, varscan2
- TMED1 | c.340A>G p.I114V | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT tolerated (0.41); PolyPhen benign (0.055); catalogued as COSV99284287; called by muse, mutect2, varscan2
- TMEM132A | c.2236G>T p.E746* (on ENST00000453848 / NM_178031.3; = p.E747* on NM_017870.4) | Nonsense Mutation (SNP) | VAF 12/29 reads (41%) | catalogued as COSV99137240; called by muse, mutect2, varscan2
- TMEM26 | c.790C>A p.Q264K | Missense Mutation (SNP) | VAF 131/211 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99515856; called by muse, mutect2, varscan2
- TOMM70 | c.1178C>T p.A393V | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99424601; called by muse, mutect2, varscan2
- TRPA1 | c.62T>C p.V21A | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV100085234; called by muse, mutect2, varscan2
- TTN | c.48929C>A p.P16310H (on ENST00000591111; = p.P8886H on NM_003319.4) | Missense Mutation (SNP) | VAF 10/100 reads (10%) | PolyPhen probably damaging (0.977); catalogued as COSV100630718, COSV60128703; called by muse, mutect2
- UBC | c.1426A>C p.S476R | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); catalogued as COSV100299141; called by mutect2, varscan2
- UBE3D | c.130C>T p.L44F | Missense Mutation (SNP) | VAF 64/129 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV99389065; called by muse, mutect2, varscan2
- ZGRF1 | c.2487A>C p.L829F | Missense Mutation (SNP) | VAF 47/117 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100005799; called by muse, mutect2, varscan2
- ZNF556 | c.905T>C p.F302S | Missense Mutation (SNP) | VAF 74/127 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.053); catalogued as COSV100298928; called by muse, mutect2, varscan2
- ZNF675 | c.1663A>C p.K555Q | Missense Mutation (SNP) | VAF 59/86 reads (69%) | SIFT tolerated (0.05); PolyPhen benign (0.378); catalogued as COSV100705198, COSV63095961; called by muse, mutect2, varscan2
- ARMC3 | c.1245dup p.A416Cfs*54 | Frame Shift Ins (INS) | VAF 47/84 reads (56%) | called by mutect2, pindel, varscan2
- DNAH10 | c.4871dup p.N1624Kfs*11 (on ENST00000409039; = p.N1563Kfs*11 on NM_207437.3) | Frame Shift Ins (INS) | VAF 25/117 reads (21%) | called by mutect2, pindel, varscan2
- HSP90AA1 | c.723_726dup p.E243Rfs*16 | Frame Shift Ins (INS) | VAF 28/145 reads (19%) | called by mutect2, pindel, varscan2
- KLF6 | c.252dup p.P85Sfs*30 | Frame Shift Ins (INS) | VAF 40/99 reads (40%) | called by mutect2, pindel, varscan2
- LRP8 | c.851_854del p.D284Afs*53 | Frame Shift Del (DEL) | VAF 6/8 reads (75%) | called by mutect2, varscan2
- LUC7L3 | c.1275dup p.E426* | Frame Shift Ins (INS) | VAF 80/301 reads (27%) | called by mutect2, pindel, varscan2
- TSC1 | c.77_78del p.T26Sfs*4 | Frame Shift Del (DEL) | VAF 12/38 reads (32%) | called by mutect2, pindel, varscan2
- UNC13D | c.1528del p.D510Tfs*38 | Frame Shift Del (DEL) | VAF 20/69 reads (29%) | called by pindel, varscan2
- ZFHX4 | c.10617_10622del p.S3540_P3541del | In Frame Del (DEL) | VAF 72/142 reads (51%) | called by mutect2, pindel, varscan2
- ACACA | c.4899A>G p.T1633= | Silent (SNP) | VAF 61/101 reads (60%) | called by muse, mutect2, varscan2
- ACAD11 | c.282G>A p.L94= | Silent (SNP) | VAF 248/403 reads (62%) | catalogued as rs144139484; called by muse, mutect2, varscan2
- ANKRD13C | c.279C>T p.A93= | Silent (SNP) | VAF 75/88 reads (85%) | catalogued as COSV99257693; called by muse, mutect2, varscan2
- ASAP2 | c.2334C>T p.A778= | Silent (SNP) | VAF 52/104 reads (50%) | catalogued as COSV99856834; called by muse, mutect2, varscan2
- BICRA | c.4419G>A p.K1473= | Silent (SNP) | VAF 38/58 reads (66%) | catalogued as COSV101194485; called by muse, mutect2, varscan2
- BRI3BP | c.525C>T p.H175= | Silent (SNP) | VAF 30/88 reads (34%) | catalogued as COSV100413195; called by muse, mutect2, varscan2
- COL18A1 | c.2832T>C p.G944= (on ENST00000359759 / NM_130444.3; = p.G709= on NM_030582.4) | Silent (SNP) | VAF 34/72 reads (47%) | catalogued as COSV100700973; called by muse, mutect2, varscan2
- CORO6 | c.840C>T p.I280= | Silent (SNP) | VAF 54/84 reads (64%) | catalogued as rs1052728788, COSV100801445; called by muse, mutect2, varscan2
- FAM126B | c.900C>G p.V300= | Silent (SNP) | VAF 26/53 reads (49%) | catalogued as COSV99628280; called by muse, mutect2, varscan2
- FBXO4 | c.135T>A p.R45= | Silent (SNP) | VAF 124/262 reads (47%) | catalogued as COSV99715306; called by muse, mutect2, varscan2
- GJA10 | c.759T>C p.D253= | Silent (SNP) | VAF 41/91 reads (45%) | catalogued as COSV101005451; called by muse, mutect2, varscan2
- HEPHL1 | c.96G>T p.G32= | Silent (SNP) | VAF 21/47 reads (45%) | catalogued as COSV100244430; called by muse, mutect2, varscan2
- INTS6 | c.1587T>A p.V529= | Silent (SNP) | VAF 82/164 reads (50%) | catalogued as COSV100247275; called by muse, mutect2, varscan2
- ITGA6 | c.2508A>G p.L836= (on ENST00000442250; = p.L797= on NM_000210.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 65/147 reads (44%) | catalogued as COSV99906122; called by muse, mutect2, varscan2
- SEMA4F | c.1284C>A p.V428= | Silent (SNP) | VAF 24/49 reads (49%) | catalogued as COSV100336164; called by muse, mutect2, varscan2
- SLC4A10 | c.1860C>T p.I620= (on ENST00000446997 / NM_001354461.2; = p.I590= on NM_022058.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 55/127 reads (43%) | catalogued as COSV99763527; called by muse, mutect2, varscan2
- UBE2O | c.2889G>A p.A963= | Silent (SNP) | VAF 20/54 reads (37%) | catalogued as rs1208615753, COSV100085062; called by muse, mutect2, varscan2
- VWF | c.4614G>A p.T1538= | Silent (SNP) | VAF 16/38 reads (42%) | catalogued as rs748377348, COSV99780207; called by muse, mutect2, varscan2
- WDR18 | c.753G>A p.R251= | Silent (SNP) | VAF 45/73 reads (62%) | catalogued as rs1179114682, COSV99243118; called by muse, mutect2
- C9orf106 | n.515C>T | RNA (SNP) | VAF 17/28 reads (61%) | called by muse, mutect2, varscan2
- ERCC6 | c.1397+7076T>A | Intron (SNP) | VAF 24/91 reads (26%) | catalogued as COSV100876237; called by muse, mutect2, varscan2
- PHF23 | c.-2C>A | 5'UTR (SNP) | VAF 38/72 reads (53%) | catalogued as COSV99138887; called by muse, mutect2, varscan2
